Somatic mutation profile of tumor specimen TCGA-AA-3956-01A (aliquot TCGA-AA-3956-01A-02W-0995-10) from TCGA case TCGA-AA-3956, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.8 years (24,045 days).
Specimen TCGA-AA-3956-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03b0d264-f14e-40c9-8ab5-ae4d76387958.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3956-10A (Blood Derived Normal), aliquot TCGA-AA-3956-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/876e0bb3-59b6-45d6-bfe4-d4c636669e30

The open-access MAF lists 140 somatic variants for this specimen: 110 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 29, Nonsense Mutation 5, Frame Shift Ins 5, Frame Shift Del 2, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTK | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555978277, CM980269, COSV58124345; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137854556, CM000802, CM983421, COSV100648616, COSV62196628, COSV62224419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 18/29 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.2989A>G p.T997A | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV54009850; called by muse, mutect2, varscan2
- AHCTF1 | c.1211G>A p.G404D (on ENST00000366508; = p.G378D on NM_015446.5) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.564); catalogued as COSV100403748; called by muse, mutect2, varscan2
- APC | c.2563_2564del p.E855Tfs*56 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs794727160; called by pindel, varscan2
- APC | c.4325del p.P1442Lfs*31 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as COSV57328830; called by mutect2, pindel, varscan2
- ARAP2 | c.1664G>T p.R555I | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100394695; called by muse, mutect2, varscan2
- ARSG | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs778128173, COSV71593687; called by muse, mutect2, varscan2
- ASCC3 | c.4247A>T p.K1416I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV100976483; called by muse, mutect2, varscan2
- AURKC | c.425G>A p.R142H (on ENST00000302804 / NM_001015878.2; = p.R108H on NM_003160.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs781321656, COSV57137565; called by muse, mutect2, varscan2
- BACH2 | c.569T>A p.I190N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV99999613; called by muse, mutect2, varscan2
- C2CD5 | c.2380A>T p.I794F | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV61728250; called by muse, mutect2, varscan2
- CACNG7 | c.10T>A p.C4S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs1173961414, COSV55813657, COSV99712049; called by muse, varscan2
- CAMTA1 | c.3413C>T p.S1138L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs750477632, COSV100349793; called by muse, mutect2, varscan2
- CHD6 | c.5293G>C p.E1765Q | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.03); catalogued as COSV100951010; called by muse, mutect2, varscan2
- COG5 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749987705, COSV51765939; called by muse, varscan2
- COL1A2 | c.1567G>A p.G523S | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99799809; called by muse, mutect2, varscan2
- COX6A2 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV54931757; called by muse, mutect2, varscan2
- CPEB2 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as rs533201180, COSV99470341; called by muse, mutect2, varscan2
- CSMD2 | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as rs767876663, COSV99590283, COSV99595753; called by muse, mutect2, varscan2
- DENND3 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164686761, COSV52802220; called by muse, mutect2, varscan2
- DNAH17 | c.2302A>T p.I768F | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67762015; called by muse, mutect2, varscan2
- DNAH8 | c.12067C>T p.R4023C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs569195029, COSV59464938; called by muse, mutect2, varscan2
- DNMT1 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1003447106, COSV100532505, COSV100532901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.8273A>T p.D2758V | Missense Mutation (SNP) | VAF 92/303 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as COSV100518642; called by mutect2, varscan2
- DYNC2LI1 | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV53185628; called by muse, mutect2, varscan2
- ELMO1 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100164491, COSV100164613; called by muse, mutect2, varscan2
- EPHB2 | c.2422G>A p.D808N (on ENST00000400191 / NM_001309193.2; = p.D809N on NM_004442.7) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007057; called by muse, mutect2, varscan2
- EXD1 | c.1214A>T p.E405V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as COSV100153638; called by muse, mutect2
- FAM47C | c.1187A>G p.K396R | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100792587; called by muse, mutect2, varscan2
- FBL | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.47); catalogued as rs749288592, COSV55682159; called by muse, mutect2, varscan2
- FMN2 | c.4309T>C p.F1437L | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100145171; called by muse, mutect2, varscan2
- FNDC1 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.057); catalogued as COSV51935830, COSV99795870; called by muse, mutect2, varscan2
- GAPVD1 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750094853, COSV52922257, COSV99783890; called by muse, mutect2, varscan2
- GLUD2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs778529221; called by muse, varscan2
- GRM4 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs528782611, COSV100946234; called by muse, mutect2, varscan2
- HBP1 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56019700; called by muse, mutect2, varscan2
- HCRTR1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV65486875; called by muse, mutect2, varscan2
- HHAT | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs1435982918, COSV54811410; called by muse, varscan2
- HNRNPA2B1 | c.878-2A>G p.X293_splice (on ENST00000354667 / NM_031243.3; = p.X281_splice on NM_002137.4) | Splice Site (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100668215, COSV61158857; called by muse, mutect2, varscan2
- HNRNPH3 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV56263453; called by muse, mutect2, varscan2
- IL1R1 | c.847A>G p.N283D | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV52108695; called by muse, mutect2, varscan2
- IL3 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.061); catalogued as rs761206378, COSV57309518; called by muse, mutect2, varscan2
- ITGBL1 | c.311G>A p.C104Y | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66027653; called by muse, mutect2, varscan2
- KCNH5 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs745970423, COSV59752965, COSV59755413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ3 | c.1075A>T p.K359* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV99715847; called by muse, mutect2, varscan2
- KIRREL3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs779979146, COSV73105940; called by muse, mutect2, varscan2
- LCA5 | c.1171A>T p.K391* | Nonsense Mutation (SNP) | VAF 29/223 reads (13%) | catalogued as COSV100878278; called by muse, mutect2, varscan2
- LOXL2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs143674437; called by muse, mutect2, varscan2
- LRP12 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99407769; called by muse, mutect2, varscan2
- MBOAT1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61128268; called by muse, mutect2, varscan2
- MEAK7 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100640399; called by muse, mutect2, varscan2
- MEX3C | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV68530899; called by muse, mutect2, varscan2
- MMP19 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs762888609, COSV59450393; called by muse, mutect2, varscan2
- MRPL21 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757166826, COSV62913423; called by muse, mutect2
- MS4A5 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV55741393; called by muse, mutect2, varscan2
- MTOR | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100816214; called by muse, mutect2, varscan2
- MYPN | c.1535G>A p.C512Y | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.478); catalogued as COSV100590007; called by muse, mutect2, varscan2
- NAA11 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs745372449, COSV54514317, COSV99727364; called by muse, mutect2, varscan2
- NELL2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs1027889753, COSV61584897; called by muse, mutect2, varscan2
- OR4P4 | c.236T>C p.L79S | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100111747, COSV58922281; called by muse, mutect2, varscan2
- OR52B4 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101281575, COSV101281592; called by muse, mutect2, varscan2
- OR5D18 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV61738853; called by muse, mutect2, varscan2
- ORC3 | c.233A>G p.Q78R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100005941; called by muse, varscan2
- PATL1 | c.1969C>T p.R657* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as COSV55690044; called by muse, mutect2, varscan2
- PCDH9 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60551808; called by muse, mutect2, varscan2
- PCDHGA6 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.113); catalogued as rs753347582, COSV53955061; called by muse, mutect2, varscan2
- PEX11A | c.283A>T p.I95F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55585408; called by muse, mutect2, varscan2
- PLEKHG4B | c.799G>A p.A267T (on ENST00000283426; = p.A623T on NM_052909.5) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV52056228; called by muse, mutect2
- PLXNB1 | c.2255G>C p.G752A | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV99602877; called by muse, mutect2, varscan2
- POSTN | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 173/785 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753830117, COSV65714455; called by muse, mutect2, varscan2
- PRKAG2 | c.865-5_871del p.X289_splice | Splice Site (DEL) | VAF 13/68 reads (19%) | catalogued as COSV55243116; called by mutect2, pindel, varscan2
- PSG1 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV99740070; called by muse, mutect2
- PTPRC | c.3273A>C p.K1091N | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV100722681; called by muse, mutect2, varscan2
- PTPRZ1 | c.2359G>T p.A787S | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.368); catalogued as COSV66446622; called by muse, mutect2, varscan2
- RAB40B | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.918); catalogued as rs1414750973, COSV53918401; called by muse, mutect2, varscan2
- REN | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99689541; called by muse, mutect2, varscan2
- RPL4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs752263296, COSV100328483, COSV100328664; called by muse, mutect2, varscan2
- SAYSD1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57723670; called by muse, mutect2, varscan2
- SHANK1 | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.456); catalogued as COSV53263839; called by muse, mutect2, varscan2
- SIDT2 | c.1372G>C p.V458L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV99637729; called by muse, mutect2, varscan2
- SLC38A7 | c.242dup p.V82Rfs*31 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs755556671; called by pindel, varscan2
- SLFN13 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99540017; called by muse, mutect2, varscan2
- SLIT2 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99884001; called by muse, mutect2, varscan2
- SOST | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs574411567, COSV57013139; called by muse, varscan2
- SPEN | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV101005249; called by muse, mutect2, varscan2
- SUN3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as rs145833872, COSV52051399; called by muse, mutect2, varscan2
- SV2A | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs781948463, COSV64964461; called by muse, mutect2, varscan2
- TP53I3 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as rs763377588, COSV99272820; called by muse, mutect2, varscan2
- TTC7A | c.1288T>A p.S430T | Missense Mutation (SNP) | VAF 77/1109 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); catalogued as CD1313074, COSV99766467; called by muse, mutect2
- TTN | c.28375G>A p.E9459K (on ENST00000591111; = p.E8532K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/173 reads (59%) | PolyPhen benign (0); catalogued as rs143477225, COSV60187778; called by muse, mutect2, varscan2
- UBE4B | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761955109, COSV53540760; called by muse, mutect2, varscan2
- UBQLNL | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV100974415; called by muse, mutect2, varscan2
- UMODL1 | c.3361G>A p.G1121R (on ENST00000408910 / NM_001004416.2; = p.G1249R on NM_173568.3) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769546147, COSV68570878; called by muse, mutect2, varscan2
- VCAM1 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.656); catalogued as COSV99658564; called by muse, mutect2, varscan2
- VPS13B | c.5423T>G p.I1808R | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV62159320; called by muse, mutect2, varscan2
- VPS50 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52498257; called by muse, mutect2, varscan2
- WSCD2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs763690309, COSV99774666; called by muse, mutect2, varscan2
- ZBBX | c.2143T>A p.S715T | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV100284060; called by muse, mutect2, varscan2
- ZC3H13 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 122/290 reads (42%) | catalogued as rs1466115407, COSV54447918; called by muse, mutect2, varscan2
- ZMYND11 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 55/486 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100556473, COSV59077179; called by muse, mutect2, varscan2
- ZNF470 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs143160710; called by muse, mutect2, varscan2
- ZNF569 | c.1946T>G p.L649R | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100386480; called by muse, mutect2, varscan2
- ZNF813 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs878881658, COSV67175568; called by muse, mutect2, varscan2
- FYN | c.1514dup p.D506Gfs*3 | Frame Shift Ins (INS) | VAF 28/156 reads (18%) | called by mutect2, pindel, varscan2
- HYDIN | c.12765_12766insG p.F4256Vfs*111 | Frame Shift Ins (INS) | VAF 4/17 reads (24%) | called by mutect2, varscan2
- PRDM11 | c.380dup p.V128Gfs*5 (on ENST00000530656 / NM_001359633.1; = p.V94Gfs*5 on NM_001256695.1) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- RNF168 | c.1523dup p.T509Nfs*11 | Frame Shift Ins (INS) | VAF 39/383 reads (10%) | called by mutect2, varscan2
- AL592490.1 | c.645G>A p.S215= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV69426263; called by muse, mutect2, varscan2
- ASIC3 | c.1401G>A p.K467= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1453575467, COSV52526360; called by muse, mutect2, varscan2
- CDH9 | c.249A>G p.K83= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV50507245; called by muse, mutect2, varscan2
- CHD5 | c.3813C>T p.D1271= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs201484104, COSV52422737; called by mutect2, varscan2
- CLEC9A | c.708G>A p.A236= | Silent (SNP) | VAF 67/256 reads (26%) | catalogued as rs745674097, COSV59534240; called by muse, mutect2, varscan2
- CLSTN3 | c.978C>T p.A326= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV56940877; called by muse, mutect2, varscan2
- COL5A3 | c.3183G>A p.G1061= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV53420364; called by muse, mutect2, varscan2
- COLEC11 | c.183C>T p.V61= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs369069794; called by muse, mutect2, varscan2
- DLGAP5 | c.1371G>A p.L457= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as rs769886984, COSV55965601; called by muse, mutect2, varscan2
- EPHB1 | c.1893A>G p.G631= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV67673004; called by muse, mutect2, varscan2
- GJA8 | c.1026C>T p.A342= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99569414; called by muse, mutect2, varscan2
- GRIA4 | c.1731G>A p.E577= | Silent (SNP) | VAF 27/173 reads (16%) | catalogued as rs1242371059, COSV99231650; called by muse, mutect2, varscan2
- HACD1 | c.666C>T p.Y222= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs782770326, COSV63516636; called by muse, mutect2, varscan2
- ITGAE | c.1869C>T p.D623= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs577050526, COSV53989682; called by muse, mutect2, varscan2
- KCNJ3 | c.1074G>A p.V358= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV54541407; called by muse, mutect2, varscan2
- KRT27 | c.708G>A p.A236= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV56971978, COSV56973101; called by muse, mutect2, varscan2
- LRRC42 | c.552G>A p.K184= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as COSV59962122; called by muse, mutect2, varscan2
- MOV10L1 | c.2985G>A p.A995= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as rs202017003, COSV53170061; called by muse, mutect2, varscan2
- MYO7A | c.5418C>T p.A1806= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs368749248; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NXF1 | c.1677G>A p.P559= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs143444714, COSV53677117; called by muse, mutect2, varscan2
- PABPC3 | c.528T>C p.R176= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV55806978; called by muse, mutect2, varscan2
- PARVG | c.75A>G p.S25= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs1417928763, COSV63563120; called by muse, mutect2, varscan2
- PDZRN4 | c.2646T>C p.C882= (on ENST00000402685 / NM_001164595.2; = p.C624= on NM_013377.4) | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV54219084; called by muse, mutect2, varscan2
- RNF43 | c.987T>A p.S329= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV68460478; called by muse, mutect2, varscan2
- SMARCD2 | c.642T>G p.T214= | Silent (SNP) | VAF 24/329 reads (7%) | catalogued as COSV99856431; called by muse, mutect2
- SPHKAP | c.1194C>T p.S398= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs201850154, COSV60894315; called by muse, mutect2, varscan2
- SYNE1 | c.26040C>A p.T8680= (on ENST00000367255 / NM_182961.4; = p.T8632= on NM_033071.3) | Silent (SNP) | VAF 318/1215 reads (26%) | catalogued as COSV55119583; called by muse, mutect2, varscan2
- TAAR2 | c.513T>A p.P171= (on ENST00000367931 / NM_001033080.1; = p.P126= on NM_014626.3) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV51580204, COSV99255673; called by muse, mutect2, varscan2
- UBASH3A | c.1662G>A p.P554= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs779550815, COSV52316652; called by muse, mutect2, varscan2
- H1-3 | c.-2A>G | 5'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as rs756730837; called by muse, mutect2, varscan2
